Somatic mutation profile of tumor specimen TCGA-BA-7269-01A (aliquot TCGA-BA-7269-01A-11D-2012-08) from TCGA case TCGA-BA-7269, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 61.9 years (22,609 days).
Specimen TCGA-BA-7269-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 273bfe69-06a1-4e78-a5cf-14bb50d319b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-7269-10A (Blood Derived Normal), aliquot TCGA-BA-7269-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d28507e-8728-47b2-ab8c-750f84c69e5e

The open-access MAF lists 98 somatic variants for this specimen: 72 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 24, Nonsense Mutation 5, Frame Shift Del 3, Splice Site 1, Frame Shift Ins 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.149A>G p.Q50R | Missense Mutation (SNP) | VAF 105/192 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587778189, CM056554, CM950228, CS022094, COSV58683689, COSV58715821; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ACTRT2 | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759246361, COSV101007494; called by muse, mutect2, varscan2
- ADAM29 | c.2070A>T p.L690F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV63665437; called by muse, mutect2, varscan2
- AHNAK | c.4935G>T p.E1645D | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.026); catalogued as rs1220259247, COSV99945636; called by muse, mutect2, varscan2
- APOBEC3B | c.905A>G p.H302R | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as COSV100213661; called by muse, mutect2
- APP | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.305); catalogued as rs147485129; called by muse, mutect2, varscan2
- AXL | c.1517G>A p.R506H (on ENST00000301178 / NM_021913.5; = p.R497H on NM_001699.6) | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1162584880, COSV56566309; called by muse, mutect2, varscan2
- BRSK1 | c.2225G>A p.R742Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.885); catalogued as rs763805486, COSV100442204; called by muse, mutect2
- C16orf71 | c.837A>C p.E279D | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV100172790; called by muse, mutect2, varscan2
- CAND2 | c.1827C>G p.D609E (on ENST00000456430 / NM_001162499.2; = p.D516E on NM_012298.3) | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1374048247, COSV99928629; called by muse, mutect2, varscan2
- CD5L | c.23T>C p.I8T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.637); catalogued as COSV100940999; called by muse, mutect2, varscan2
- CMPK1 | c.297A>G p.I99M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100898547; called by muse, mutect2, varscan2
- COPS7B | c.83C>A p.T28N | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV100602188; called by muse, mutect2
- CSTF2 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV100802903; called by muse, mutect2, varscan2
- DMD | c.7193C>A p.P2398Q | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.48); PolyPhen benign (0.053); catalogued as COSV100626033; called by muse, mutect2, varscan2
- E2F7 | c.815C>A p.P272H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV100523314; called by muse, mutect2, varscan2
- ECI2 | c.7A>G p.M3V | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs765201457, COSV100326312; called by muse, mutect2, varscan2
- FAM71B | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV100261816, COSV100262008; called by muse, mutect2, varscan2
- FAM71B | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as COSV100261817, COSV57229619; called by muse, mutect2, varscan2
- FANCD2 | c.3029A>G p.Q1010R | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.076); catalogued as rs376836572; called by muse, mutect2, varscan2
- FBXL4 | c.35C>G p.T12S | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs771325698, COSV57750897; called by muse, mutect2, varscan2
- FUBP1 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99627831; called by muse, mutect2, varscan2
- GCM1 | c.1168C>T p.L390F | Missense Mutation (SNP) | VAF 13/304 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as COSV99452116; called by muse, mutect2
- HLA-DMB | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.086); catalogued as COSV101186813; called by muse, mutect2, varscan2
- HLA-F | c.735G>C p.Q245H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV99465655; called by muse, mutect2, varscan2
- KEAP1 | c.1792A>G p.T598A | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV99407348; called by muse, mutect2, varscan2
- LCLAT1 | c.807G>C p.E269D | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100473510; called by muse, mutect2, varscan2
- LRRN2 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781028138, COSV65783362; called by muse, mutect2, varscan2
- LYST | c.4631C>A p.S1544Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101088240, COSV67714393; called by muse, mutect2, varscan2
- MRPL39 | c.181C>G p.R61G | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100220844; called by muse, mutect2, varscan2
- NEFH | c.923C>T p.T308I | Missense Mutation (SNP) | VAF 58/351 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as COSV100151259; called by muse, mutect2, varscan2
- NFATC2IP | c.1199G>T p.G400V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100297493; called by muse, mutect2, varscan2
- NFE2L2 | c.786C>G p.D262E | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV101229308; called by muse, mutect2, varscan2
- NOL8 | c.2995G>C p.E999Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV100694453; called by muse, mutect2
- OLFM3 | c.691G>T p.V231F (on ENST00000338858 / NM_001288821.1; = p.V211F on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.487); catalogued as COSV100128904; called by muse, mutect2, varscan2
- OR2M2 | c.1012A>G p.K338E | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV62897741; called by muse, mutect2, varscan2
- PABPC4 | c.830A>T p.K277I | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100790853; called by muse, mutect2, varscan2
- PAPPA2 | c.4402G>T p.D1468Y | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs371564283, COSV62814657; called by muse, mutect2, varscan2
- PCDHA12 | c.1633C>G p.L545V | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56492417; called by muse, mutect2, varscan2
- PCDHGB6 | c.523A>C p.N175H | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV99531001; called by muse, mutect2, varscan2
- PCGF5 | c.747T>G p.Y249* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100277525; called by muse, mutect2
- PEAK1 | c.53A>G p.K18R | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100432428; called by muse, mutect2, varscan2
- PEX6 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.4); catalogued as rs763917905, COSV55102293, COSV99770042; called by muse, mutect2, varscan2
- PLD1 | c.2048C>T p.S683F | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.809); catalogued as COSV60570111; called by muse, mutect2
- POTEE | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.556); catalogued as rs761896133, COSV58236334; called by muse, varscan2
- RAI1 | c.1442G>T p.C481F | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99883407; called by muse, mutect2, varscan2
- RANBP10 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs768116527, COSV100449127; called by muse, mutect2, varscan2
- RFX5 | c.703C>A p.L235I | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.386); catalogued as COSV100923824; called by muse, mutect2, varscan2
- RPS6KC1 | c.3085C>T p.Q1029* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100873771; called by muse, mutect2, varscan2
- RTN3 | c.2211C>A p.D737E (on ENST00000377819 / NM_001265589.2; = p.D718E on NM_201428.3) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100379874; called by muse, mutect2, varscan2
- SETD2 | c.3919G>C p.D1307H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV100338016; called by muse, mutect2, varscan2
- SIM1 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99491937; called by muse, mutect2, varscan2
- SLC23A2 | c.473T>C p.F158S | Missense Mutation (SNP) | VAF 79/272 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV100594781; called by muse, mutect2, varscan2
- SLC4A7 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99839218; called by muse, mutect2, varscan2
- SLC8A2 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.084); catalogued as COSV99369665; called by muse, mutect2, varscan2
- SSTR3 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs371788740; called by muse, mutect2, varscan2
- TCEANC2 | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.367); catalogued as rs762234407, COSV99328544; called by muse, mutect2, varscan2
- TMEM131L | c.3032G>A p.S1011N | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV99546830; called by muse, mutect2, varscan2
- TP53 | c.668_669insA p.E224* | Frame Shift Ins (INS) | VAF 7/28 reads (25%) | catalogued as COSV99370434; called by mutect2, pindel, varscan2
- TTC37 | c.4012G>C p.D1338H | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.229); catalogued as COSV100706377, COSV100706609; called by muse, mutect2, varscan2
- TTN | c.48548T>C p.I16183T (on ENST00000591111; = p.I8759T on NM_003319.4) | Missense Mutation (SNP) | VAF 25/160 reads (16%) | PolyPhen possibly damaging (0.844); catalogued as rs765709539, COSV100594885; called by muse, mutect2, varscan2
- UGT2B4 | c.721+2T>C p.X241_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | catalogued as rs377159596; called by muse, mutect2, varscan2
- USP15 | c.575A>G p.N192S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs765197962, COSV99738574; called by muse, mutect2, varscan2
- VENTX | c.345C>G p.Y115* | Nonsense Mutation (SNP) | VAF 29/65 reads (45%) | catalogued as COSV100383992; called by muse, mutect2, varscan2
- VWA3B | c.2486C>T p.T829M | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.226); catalogued as rs375038927; called by muse, mutect2, varscan2
- XRN2 | c.614A>G p.E205G | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101017987; called by muse, mutect2, varscan2
- ZBED9 | c.3010G>T p.E1004* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV101509122; called by muse, mutect2, varscan2
- ZNF142 | c.2005A>T p.K669* (on ENST00000411696 / NM_001379660.1; = p.K469* on NM_001105537.4 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 44/102 reads (43%) | catalogued as COSV101376901; called by muse, mutect2, varscan2
- ZNF709 | c.1349G>T p.C450F | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101172084; called by muse, mutect2, varscan2
- ARHGAP5 | c.629_642del p.R210Ifs*5 | Frame Shift Del (DEL) | VAF 11/68 reads (16%) | called by mutect2, pindel, varscan2
- ATP8B2 | c.278_281del p.Y93Sfs*9 (on ENST00000672630; = p.Y60Sfs*9 on NM_001005855.2) | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by pindel, varscan2
- FAT1 | c.2250_2256del p.K751Sfs*14 | Frame Shift Del (DEL) | VAF 61/90 reads (68%) | called by mutect2, pindel, varscan2
- ANKS3 | c.498G>A p.P166= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1288118627, COSV100422917; called by muse, mutect2, varscan2
- ASPM | c.6108G>T p.V2036= | Silent (SNP) | VAF 55/118 reads (47%) | catalogued as COSV99659574; called by muse, mutect2, varscan2
- CALHM1 | c.279C>T p.P93= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs1052246091, COSV100324123; called by muse, mutect2, varscan2
- CAMTA1 | c.3777G>A p.K1259= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100346402; called by muse, mutect2, varscan2
- CAMTA1 | c.3778C>T p.L1260= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100346405; called by muse, mutect2, varscan2
- CDC6 | c.876A>G p.K292= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as COSV99266495; called by muse, mutect2, varscan2
- CDH11 | c.1708C>T p.L570= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV51773591; called by muse, mutect2, varscan2
- DCAF12L1 | c.873C>T p.A291= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV64421343; called by muse, mutect2, varscan2
- DSEL | c.1026C>A p.S342= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV100025279; called by muse, mutect2, varscan2
- FLRT2 | c.993T>C p.S331= | Silent (SNP) | VAF 38/271 reads (14%) | catalogued as COSV100420012; called by muse, mutect2, varscan2
- GCNT1 | c.453C>T p.C151= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs780811950, COSV100946454; called by muse, mutect2, varscan2
- IDE | c.351A>G p.G117= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV99793802; called by muse, mutect2, varscan2
- INPP4A | c.933C>T p.D311= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV99302592; called by muse, mutect2
- PAQR8 | c.756C>A p.I252= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV100658382; called by muse, mutect2, varscan2
- PTPN6 | c.864C>T p.I288= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100016910; called by muse, mutect2, varscan2
- SACS | c.300C>G p.L100= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV101207175; called by muse, mutect2, varscan2
- SIGLEC11 | c.330C>T p.G110= | Silent (SNP) | VAF 12/125 reads (10%) | catalogued as COSV101389066; called by muse, mutect2, varscan2
- SLC12A8 | c.366C>T p.I122= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as rs757205892, COSV58872715; called by muse, mutect2, varscan2
- STEAP4 | c.1065G>A p.G355= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV100112386; called by muse, mutect2, varscan2
- TBC1D3F | c.18C>T p.V6= | Silent (SNP) | VAF 136/414 reads (33%) | catalogued as rs1361709788; called by muse, mutect2, varscan2
- TBCK | c.2472A>C p.A824= (on ENST00000273980 / NM_001163436.4; = p.A761= on NM_033115.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs1402807498, COSV99912063; called by muse, mutect2, varscan2
- TRRAP | c.11019C>A p.T3673= (on ENST00000359863 / NM_001244580.1; = p.T3644= on NM_003496.3) | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV100705363; called by muse, mutect2, varscan2
- ZNF185 | c.1383C>T p.V461= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV100248160; called by muse, mutect2, varscan2
- ZNF302 | c.861A>G p.K287= (on ENST00000627982; = p.K208= on NM_018443.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 59/125 reads (47%) | catalogued as COSV101416433; called by muse, mutect2, varscan2
- MIR518B | n.82G>C | RNA (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- NDUFA3 | c.*105G>A | 3'UTR (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100338110; called by muse, mutect2, varscan2
